Gene-level copy-number profile of tumor specimen TCGA-90-7766-01A from TCGA case TCGA-90-7766, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.7 years (24,354 days).
Specimen TCGA-90-7766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.77702ea0-daa4-4d5e-bad0-c0be4776ae07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-90-7766-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/66b99575-037d-4f4f-aa27-8babc0b935a5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 15,424; copy number 2: 40,473; copy number 3: 1,949; copy number 4: 1,678; copy number 5: 12; copy number 6: 174; copy number 8: 5; copy number 10: 55; copy number 19: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-90-7766-01A-21D-2121-01): tumor purity 0.59, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:13,738,537–14,398,983, 8 genes (within-gene range 0–1): AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 11 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 272 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,072,915–69,162,440, 1 gene, copy number 10 (within-gene range 2–10): AP003071.5.
- chr11:69,147,228–73,397,474, 144 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr14:28,726,675–29,372,406, 12 genes, copy number 5 (within-gene range 1–5): FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P.
- chr14:36,136,108–38,041,442, 34 genes, copy number 10–19: PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1.
- chr18:42,649,520–48,410,752, 81 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,424. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
